CPTAC case C3N-03027 — Floor of mouth — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/39f5218a-5a5c-452a-916a-d840fa9757d8

Demographics
Sex at birth: male; Race: white; Year of birth: 1952; Vital status: Dead; Days to death: 211 days; Year of death: 2018; Cause of death: Not Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Floor of mouth, NOS; Age at diagnosis: 65.4 years (23,896 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 211 days; Progression or recurrence: no; Days to last follow up: 211 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 211 days; Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 310 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 0.

Other clinical attributes
- Weight: 62 kg; Height: 174 cm; BMI: 20.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 48; Cigarettes per day: 20; Tobacco smoking onset year: 1969; Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Exposure duration years: 53; Type of tobacco used: Smokeless Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03027-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 170 mg; Time between excision and freezing: 6 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03027-21: Section location: Floor of Mouth; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3N-03027-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 317 mg; Time between excision and freezing: 6 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03027-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -9 days; Method of sample procurement: Blood Draw.
